Somatic mutation profile of tumor specimen TCGA-17-Z013-01A (aliquot TCGA-17-Z013-01A-01W-0746-08) from TCGA case TCGA-17-Z013, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db9f2f65-f468-4bad-bbc8-a4c7ff6b0ea8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z013-11A (Solid Tissue Normal), aliquot TCGA-17-Z013-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6be43ec2-ea47-4fc8-a212-d87eec7bc88c

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 2, Translation Start Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.10100G>T p.R3367L | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs759549373; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs201799893, CM110176, COSV56683485; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- APC | c.2869A>T p.K957* | Nonsense Mutation (SNP) | VAF 28/38 reads (74%) | catalogued as COSV57333952; called by muse, mutect2, varscan2
- BCORL1 | c.1929del p.M644Cfs*4 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs1229639561; called by mutect2, pindel, varscan2
- CHM | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs770650130; called by muse, mutect2, varscan2
- DCBLD1 | c.972A>G p.I324M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99758128; called by muse, mutect2
- DNHD1 | c.12133C>A p.R4045S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553948939; called by muse, mutect2, varscan2
- EIF4G3 | c.3094G>T p.E1032* | Nonsense Mutation (SNP) | VAF 51/442 reads (12%) | catalogued as COSV51684594; called by muse, varscan2
- EMSY | c.2413A>G p.M805V | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs768079073; called by muse, mutect2, varscan2
- EYA1 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1462564075; called by muse, mutect2, varscan2
- FAM210A | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59184427; called by muse, mutect2
- GCKR | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.041); catalogued as rs779171513, COSV53106535; called by muse, mutect2, varscan2
- GSN | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs771287868; called by muse, varscan2
- HPN | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.386); catalogued as rs368912553; called by muse, mutect2, varscan2
- HTT | c.6593C>T p.P2198L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs777249004; called by muse, mutect2
- KLHL15 | c.1150del p.V384* | Frame Shift Del (DEL) | VAF 55/120 reads (46%) | catalogued as COSV60142089; called by mutect2, pindel, varscan2
- LRMDA | c.47+1G>T p.X16_splice | Splice Site (SNP) | VAF 7/77 reads (9%) | catalogued as rs1379246986; called by muse, mutect2
- MEST | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs371069028; called by muse, mutect2, varscan2
- PABPC3 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1334656474; called by muse, mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | catalogued as rs756801119; called by mutect2, varscan2
- PTPRB | c.1162A>G p.N388D | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.232); catalogued as rs761436274; called by muse, varscan2
- SLC4A10 | c.1310G>T p.R437L (on ENST00000446997 / NM_001354461.2; = p.R407L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1242764753, COSV55770206, COSV55774465; called by muse, mutect2, varscan2
- ZDHHC9 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs764639044; called by muse, mutect2, varscan2
- ZNF107 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100788409; called by muse, mutect2
- ABCA8 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAMTS20 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRG4 | c.3593C>A p.A1198D | Missense Mutation (SNP) | VAF 107/378 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CLCN3 | c.1502G>A p.W501* | Nonsense Mutation (SNP) | VAF 83/130 reads (64%) | called by muse, mutect2, varscan2
- DCAF12 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EID3 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2
- EPS8 | c.133dup p.Y45Lfs*2 | Frame Shift Ins (INS) | VAF 37/106 reads (35%) | called by mutect2, pindel, varscan2
- F8 | c.2995G>T p.G999* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- GPLD1 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- IGHG2 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 108/432 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA2 | c.780A>G p.R260= | Splice Region (SNP) | VAF 30/38 reads (79%) | called by muse, mutect2, varscan2
- KDM5C | c.1604A>G p.Y535C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- KIAA1109 | c.7997C>G p.S2666* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- LRP1B | c.3320-2del p.X1107_splice | Splice Site (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- MMP7 | c.97del p.E33Nfs*23 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- PASD1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PJA1 | c.1525G>T p.V509L (on ENST00000361478 / NM_145119.4; = p.V321L on NM_022368.5) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RFC5 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SERPINB3 | c.601dup p.W201Lfs*50 | Frame Shift Ins (INS) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- SLC44A5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 50/65 reads (77%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST18 | c.1664C>A p.P555H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TACC2 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM131 | c.826A>G p.K276E | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTC14 | c.1554G>T p.R518S | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- UBE4B | c.3829_3835del p.E1277Cfs*8 (on ENST00000343090 / NM_001105562.3; = p.E1148Cfs*8 on NM_006048.5) | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- WDR49 | c.1593A>T p.R531S (on ENST00000308378 / NM_001366158.1; = p.R872S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZDHHC22 | c.786T>A p.D262E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF8L1 | c.1011G>T p.L337= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- KCNMB1 | c.411C>T p.S137= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs779701228; called by muse, mutect2, varscan2
- MAGEA1 | c.357C>A p.A119= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100756696; called by muse, varscan2
- MAGEA12 | c.612C>T p.I204= | Silent (SNP) | VAF 14/201 reads (7%) | catalogued as rs1556833534, COSV63295561; called by muse, mutect2
- MCF2L | c.1167C>T p.H389= (on ENST00000375608; = p.H357= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs759949237; called by muse, varscan2
- MET | c.2088A>T p.T696= | Silent (SNP) | VAF 42/118 reads (36%) | called by muse, mutect2, varscan2
- NTRK3 | c.2499C>A p.I833= (on ENST00000360948 / NM_001012338.2; = p.I819= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV100713917; called by muse, mutect2, varscan2
- PIP4K2C | c.648G>A p.K216= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- POM121L12 | c.864C>T p.T288= | Silent (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.768C>A p.V256= | Silent (SNP) | VAF 62/166 reads (37%) | called by muse, mutect2, varscan2
- SLC25A36 | c.702C>T p.A234= | Silent (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- SRP68 | c.1833C>T p.T611= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- SUCLG1 | c.207C>T p.T69= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- AP4S1 | c.306+60G>T | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
